CPTAC case C3L-00908 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/763e0702-8379-4b5e-95d1-a84f412c51e7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 60.7 years (22,179 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,785 days (4.9 years); Progression or recurrence: yes; Days to last follow up: 1,785 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10.5 cm (a second GDC size field records 6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 348 days; Disease response: Tumor Free.
- Days to follow up: 649 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,055 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,419 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,419 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,785 days (4.9 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 74 kg; Height: 163 cm; BMI: 27.85.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 3; Cigarettes per day: 12; Tobacco smoking onset year: 1984; Tobacco smoking quit year: 1989; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 5.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00908-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 313 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00908-21: Section location: Left Central Anterior; Percent tumor nuclei: 90; Percent necrosis: 5.
- Sample C3L-00908-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 196 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00908-23: Section location: Left Central Anterior; Percent tumor nuclei: 0; Percent necrosis: 80.
- Sample C3L-00908-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -10 days; Initial weight: 303 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00908-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -10 days; Method of sample procurement: Blood Draw.
